Somatic mutation profile of tumor specimen 0DR1ZC from CCDI case PBCFZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,781 days).
Specimen 0DR1ZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de1092bc-8430-4487-8198-0c36af98096f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c6f1249-29c5-4bb6-be9d-7dc2074e68ee

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 5'UTR 2, Intron 2, 3'UTR 1, Frame Shift Del 1, 5'Flank 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6391C>T p.R2131* | Nonsense Mutation (SNP) | VAF 484/871 reads (56%) | catalogued as COSV64873907, COSV64881210; called by muse, mutect2, varscan2
- SHANK2 | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 373/983 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs781820650, COSV53592985; called by muse, mutect2, varscan2
- BSN | c.7078T>A p.S2360T | Missense Mutation (SNP) | VAF 173/470 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 38/1522 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- EIF3M | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 40/1726 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- ERCC6 | c.80A>G p.E27G | Missense Mutation (SNP) | VAF 35/1481 reads (2%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- GRAMD4 | c.920A>C p.Q307P | Missense Mutation (SNP) | VAF 36/619 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- HSPBP1 | c.4T>G p.S2A | Missense Mutation (SNP) | VAF 172/396 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6C3 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 564/1743 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PIK3R1 | c.2150C>A p.P717Q (on ENST00000521381 / NM_181523.3; = p.P447Q on NM_181504.4) | Missense Mutation (SNP) | VAF 82/2102 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMC1 | c.2162A>G p.K721R | Missense Mutation (SNP) | VAF 529/1363 reads (39%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TSC2 | c.1333del p.L445Cfs*4 | Frame Shift Del (DEL) | VAF 169/521 reads (32%) | called by mutect2, pindel, varscan2
- ZNF136 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 215/554 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FHOD3 | c.2316C>T p.V772= (on ENST00000359247 / NM_001281739.3; = p.V789= on NM_025135.5) | Silent (SNP) | VAF 22/647 reads (3%) | catalogued as rs1364308998, COSV57170482; called by muse, mutect2
- DMAC2 | c.597-65A>G | Intron (SNP) | VAF 98/233 reads (42%) | called by muse, mutect2, varscan2
- GPI | c.865+91C>T | Intron (SNP) | VAF 58/128 reads (45%) | called by muse, mutect2, varscan2
- TNFRSF25 | c.*12C>A | 3'UTR (SNP) | VAF 40/979 reads (4%) | called by muse, mutect2
- UNC5A | c.-73G>T | 5'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ZNF286A | chr17:15699745 A>G | 5'Flank (SNP) | VAF 320/1092 reads (29%) | called by muse, varscan2
- ZNF488 | c.-39C>T | 5'UTR (SNP) | VAF 22/584 reads (4%) | called by muse, mutect2
